Somatic mutation profile of tumor specimen TCGA-F6-A8O4-01A (aliquot TCGA-F6-A8O4-01A-11D-A36O-08) from TCGA case TCGA-F6-A8O4, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 44.4 years (16,202 days).
Specimen TCGA-F6-A8O4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a97fef9b-5f25-4af0-8e59-839f77652259.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F6-A8O4-10A (Blood Derived Normal), aliquot TCGA-F6-A8O4-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a53880b-e19e-473c-9711-44165c327f13

The open-access MAF lists 27 somatic variants for this specimen: 24 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 21, Silent 3, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 27/77 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.392A>G p.N131S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as CM087281, CM159290, COSV52670715, COSV52718021, COSV53252418; called by muse, mutect2, varscan2
- ABHD17B | c.317A>G p.Q106R | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100330027; called by muse, mutect2, varscan2
- CNOT6 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.58); catalogued as COSV99993382; called by muse, mutect2, varscan2
- CXCR1 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1268004402, COSV99826214; called by muse, mutect2, varscan2
- DEFB113 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs1209328851, COSV59038214; called by muse, mutect2
- DIRAS3 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as COSV63970471, COSV63970813; called by muse, mutect2, varscan2
- HERC1 | c.7220G>A p.G2407D | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.31); catalogued as COSV101496302; called by muse, mutect2, varscan2
- IQCG | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as rs374525402; called by muse, mutect2, varscan2
- NLRP14 | c.2012C>A p.T671K | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as COSV100204488, COSV55066114; called by muse, mutect2, varscan2
- NLRP2 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs775271805, COSV99671830; called by muse, mutect2, varscan2
- NOVA1 | c.1511_1512insC p.Q504Hfs*55 | Frame Shift Ins (INS) | VAF 16/64 reads (25%) | catalogued as COSV99946348; called by mutect2, pindel, varscan2
- PHF5A | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV53439668, COSV53440444; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2630C>T p.A877V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1366226289, COSV99769646; called by muse, mutect2
- SCN11A | c.5087G>A p.G1696D | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100180827; called by muse, mutect2, varscan2
- SPTLC2 | c.1507A>G p.I503V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs749094454, COSV99377134; called by muse, mutect2, varscan2
- STYXL2 | c.3295G>A p.G1099R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV54806458, COSV99608524; called by muse, mutect2, varscan2
- TLE4 | c.1969C>T p.H657Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as COSV99511036; called by muse, mutect2, varscan2
- UBQLN1 | c.1148A>G p.Q383R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV99973094; called by muse, mutect2, varscan2
- YWHAG | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.288); catalogued as COSV100297301; called by muse, mutect2, varscan2
- ZNF107 | c.1802T>C p.I601T | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV100788197; called by muse, mutect2, varscan2
- ATRX | c.1079_1082del p.I360Rfs*6 | Frame Shift Del (DEL) | VAF 67/87 reads (77%) | called by mutect2, pindel, varscan2
- PPP2R2D | c.682del p.M228Wfs*4 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | called by mutect2, pindel, varscan2
- APC | c.4965A>C p.T1655= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as rs863224282, COSV99964950; ClinVar: likely benign; called by muse, mutect2, varscan2
- GLMP | c.1221A>G p.*407= | Silent (SNP) | VAF 38/95 reads (40%) | catalogued as COSV99827718; called by muse, mutect2, varscan2
- MMP10 | c.666C>A p.S222= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV99666319; called by muse, mutect2, varscan2
